Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A9VF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A9VF-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – skin, left leg, lower thigh region, surgical resection

Microscopic description:

Received material is malignant melanoma with features of mixed epitheloid and spindle cell melanoma. Grade 3, Clark II- III, Breslow 0,79mm, Tumor content 80% with 5 % stroma present.

Final diagnosis: Mixed epitheloid and spindle cell melanoma.

*ICD-O-3
Melanoma, epitheloid & spindle cell mixed
Site: Right thigh C49.2
8720/3
2012/14*

Confidential

Source: NCI Genomic Data Commons file 88a823ae-a01b-4e87-a6f4-20da412c52c6 (TCGA-BF-A9VF.FDBA635C-E51D-4E19-8084-ED2EF54FAC0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).